Gene-level copy-number profile of tumor specimen HCM-CSHL-0434-C24-01A from HCMI case HCM-CSHL-0434-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,282 days).
Specimen HCM-CSHL-0434-C24-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 791c84a9-b041-446c-9a24-421eeead3e73.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0434-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/da32a754-ebec-481c-bffe-3636b22924a8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 541; copy number 1: 131; copy number 2: 13,146; copy number 3: 12,225; copy number 4: 17,841; copy number 5: 8,930; copy number 6: 5,012; copy number 7: 337; copy number 8: 413; copy number 9: 4; copy number 10: 55; copy number 11: 81; copy number 12: 18; copy number 15: 51; copy number 18: 59; copy number 20: 7; copy number 37: 58.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–22,214,672, 23 genes: MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 333 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:112,422,887–116,954,334, 55 genes, copy number 11 (within-gene range 3–11): IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30, AC073137.1, AC073348.1, PPP1R3A, FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7.
- chr7:117,262,918–120,227,213, 23 genes, copy number 11 (within-gene range 11–12): AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8, ANKRD7, GTF3AP6, AC092098.1, AC079791.1, LINC02476, RNU1-29P, AC004946.1, AC004946.2.
- chr14:32,934,396–33,804,176, 3 genes, copy number 11: NPAS3, AL161851.1, AL161851.2.
- chr19:29,489,775–29,824,312, 7 genes, copy number 20 (within-gene range 7–20): AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1.
- chr19:32,719,753–35,717,038, 132 genes, copy number 10–18 (broad region; genes not listed).
- chr19:38,647,649–38,769,904, 4 genes, copy number 9: ACTN4, AC008649.2, CAPN12, AC022144.1.
- chr19:38,975,161–40,898,282, 109 genes, copy number 15–37 (within-gene range 4–37) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 123. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
